Somatic mutation profile of tumor specimen C3L-04787-02 (aliquot CPT0250070006) from CPTAC case C3L-04787, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIC; Age at diagnosis: 90 years or older (exact value withheld by GDC).
Specimen C3L-04787-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Skin; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e0232ab2-ccc8-4fe1-892b-3ef5cf55b060.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-04787-31 (Blood Derived Normal), aliquot CPT0250160002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8e4bdb5a-5f86-4925-b038-4509ead6b5c9

The open-access MAF lists 563 somatic variants for this specimen: 359 protein-altering or splice-affecting, 178 silent, 26 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 337, Silent 178, Intron 19, Nonsense Mutation 13, Splice Region 4, 5'Flank 4, Frame Shift Del 3, Frame Shift Ins 1, 3'UTR 1, 3'Flank 1, 5'UTR 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 223/435 reads (51%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCC12 | c.96G>A p.M32I | Missense Mutation (SNP) | VAF 92/377 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.146); catalogued as rs763316759; called by muse, mutect2, varscan2
- ABCC8 | c.2507G>A p.R836Q | Missense Mutation (SNP) | VAF 103/419 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs765626111, COSV56856749; called by muse, mutect2, varscan2
- ACAN | c.148C>T p.P50S | Missense Mutation (SNP) | VAF 22/662 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV61369449; called by muse, mutect2
- ADAMDEC1 | c.499G>A p.E167K | Missense Mutation (SNP) | VAF 117/546 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.069); catalogued as rs764781260; called by muse, mutect2, varscan2
- ADAMTS10 | c.3001C>T p.R1001C | Missense Mutation (SNP) | VAF 171/647 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.443); catalogued as rs1555736584, COSV54352681; called by muse, mutect2, varscan2
- ADAMTS19 | c.707C>T p.P236L | Missense Mutation (SNP) | VAF 83/549 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.743); catalogued as COSV50789229; called by muse, mutect2, varscan2
- ADGRE3 | c.505G>A p.E169K | Missense Mutation (SNP) | VAF 102/433 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.831); catalogued as COSV53728286, COSV53734828; called by muse, mutect2, varscan2
- AGMAT | c.713G>A p.R238Q | Missense Mutation (SNP) | VAF 67/217 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.047); catalogued as rs771473311, COSV101011817, COSV101011831; called by muse, mutect2, varscan2
- AK5 | c.870G>T p.Q290H (on ENST00000354567 / NM_174858.3; = p.Q264H on NM_012093.4) | Missense Mutation (SNP) | VAF 40/298 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.025); catalogued as COSV100643538; called by muse, mutect2, varscan2
- AK9 | c.946C>T p.R316C | Missense Mutation (SNP) | VAF 44/248 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs868260985, COSV53419508; called by muse, mutect2, varscan2
- AKR7A3 | c.325C>G p.L109V | Missense Mutation (SNP) | VAF 85/355 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.777); catalogued as COSV64389302, COSV64389356; called by muse, mutect2, varscan2
- ALG14 | c.262C>T p.R88* | Nonsense Mutation (SNP) | VAF 51/497 reads (10%) | catalogued as rs200774756; called by muse, mutect2, varscan2
- AMFR | c.1603G>A p.E535K | Missense Mutation (SNP) | VAF 75/303 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.01); catalogued as rs761694034, COSV51922642; called by muse, mutect2, varscan2
- ANK1 | c.3109G>A p.D1037N | Missense Mutation (SNP) | VAF 52/279 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.665); catalogued as COSV99225602; called by muse, mutect2, varscan2
- APOL1 | c.643G>A p.G215R | Missense Mutation (SNP) | VAF 104/824 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs1198962367, COSV59868866; called by muse, mutect2, varscan2
- ATP11C | c.1168G>A p.E390K | Missense Mutation (SNP) | VAF 89/446 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs753082643; called by muse, mutect2, varscan2
- ATP1B1 | c.421C>A p.H141N | Missense Mutation (SNP) | VAF 96/446 reads (22%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs1011332391; called by muse, mutect2, varscan2
- ATP2B1 | c.2477C>T p.S826F | Missense Mutation (SNP) | VAF 61/246 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53814194; called by muse, mutect2, varscan2
- ATXN7L2 | c.562C>T p.P188S | Missense Mutation (SNP) | VAF 232/496 reads (47%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV63992976; called by muse, mutect2, varscan2
- BCOR | c.2282G>A p.R761Q | Missense Mutation (SNP) | VAF 123/584 reads (21%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.663); catalogued as rs1238639795, COSV60712554; called by muse, mutect2, varscan2
- BDKRB1 | c.700G>A p.E234K | Missense Mutation (SNP) | VAF 144/446 reads (32%) | SIFT tolerated (0.49); PolyPhen benign (0.062); catalogued as rs200369442; called by muse, mutect2, varscan2
- BPIFB3 | c.1111C>T p.P371S | Missense Mutation (SNP) | VAF 88/404 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.409); catalogued as rs779897404; called by muse, mutect2, varscan2
- BROX | c.1018C>T p.P340S | Missense Mutation (SNP) | VAF 60/273 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as rs751491598; called by muse, mutect2, varscan2
- C7 | c.2158G>A p.E720K | Missense Mutation (SNP) | VAF 66/273 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs761703740, COSV57473318; called by muse, mutect2, varscan2
- CAD | c.2662C>T p.R888C | Missense Mutation (SNP) | VAF 56/254 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs375233070; called by muse, mutect2, varscan2
- CALCRL | c.1220G>A p.G407E | Missense Mutation (SNP) | VAF 65/335 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.02); catalogued as COSV101131056, COSV66476376; called by muse, mutect2, varscan2
- CASR | c.2827G>A p.E943K (on ENST00000490131; = p.E1020K on NM_000388.4) | Missense Mutation (SNP) | VAF 121/470 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.024); catalogued as rs1060502858, COSV56141388; called by muse, mutect2, varscan2
- CC2D1A | c.2377C>T p.P793S | Missense Mutation (SNP) | VAF 70/438 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54308223, COSV54310166; called by muse, mutect2, varscan2
- CCNE1 | c.905C>T p.S302L | Missense Mutation (SNP) | VAF 48/327 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1449890888, COSV52904016; called by muse, mutect2, varscan2
- CD163 | c.1607G>A p.G536E | Missense Mutation (SNP) | VAF 107/449 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV63131336; called by muse, mutect2, varscan2
- CD1A | c.151G>A p.D51N | Missense Mutation (SNP) | VAF 223/477 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.19); catalogued as COSV56862226; called by muse, mutect2, varscan2
- CD300A | c.206G>A p.G69E | Missense Mutation (SNP) | VAF 104/431 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs754986019, COSV60409512; called by muse, mutect2, varscan2
- CD80 | c.490A>G p.T164A | Missense Mutation (SNP) | VAF 117/489 reads (24%) | SIFT tolerated (0.24); PolyPhen benign (0.1); catalogued as COSV51802046; called by muse, mutect2, varscan2
- CDC42BPA | c.4075C>T p.P1359S (on ENST00000334218 / NM_001366019.2; = p.P1346S on NM_003607.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 62/393 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.175); catalogued as COSV62009361; called by muse, mutect2, varscan2
- CEP126 | c.3145C>A p.L1049I | Missense Mutation (SNP) | VAF 81/271 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.856); catalogued as COSV54831049; called by muse, mutect2, varscan2
- CEP152 | c.3754G>A p.E1252K (on ENST00000380950 / NM_001194998.2; = p.E1196K on NM_014985.4) | Missense Mutation (SNP) | VAF 42/418 reads (10%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.81); catalogued as rs1445102224; called by muse, mutect2
- CEP290 | c.3757C>T p.R1253C | Missense Mutation (SNP) | VAF 118/369 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs547677441; called by muse, mutect2, varscan2
- CFHR5 | c.161C>T p.S54F | Missense Mutation (SNP) | VAF 101/299 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.566); catalogued as COSV56823478; called by muse, mutect2, varscan2
- CIC | c.1192C>T p.P398S | Missense Mutation (SNP) | VAF 84/531 reads (16%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.003); catalogued as rs1371700095; called by muse, mutect2, varscan2
- CMYA5 | c.9280C>T p.P3094S | Missense Mutation (SNP) | VAF 83/384 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.197); catalogued as COSV71410046; called by muse, mutect2, varscan2
- CNTN1 | c.814G>A p.D272N | Missense Mutation (SNP) | VAF 54/297 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.097); catalogued as rs1407407442, COSV61645628; called by muse, mutect2, varscan2
- COL20A1 | c.3157G>A p.D1053N | Missense Mutation (SNP) | VAF 75/341 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.061); catalogued as COSV58916897; called by muse, mutect2, varscan2
- COL2A1 | c.1756C>T p.R586C | Missense Mutation (SNP) | VAF 93/404 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs753308111, COSV61530759; called by muse, mutect2, varscan2
- COL4A5 | c.3067C>T p.P1023S | Missense Mutation (SNP) | VAF 86/446 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.357); catalogued as COSV60361757; called by muse, mutect2, varscan2
- COL5A2 | c.1171C>A p.P391T | Missense Mutation (SNP) | VAF 63/334 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.19); catalogued as COSV66411198; called by muse, mutect2, varscan2
- CPNE4 | c.1616G>A p.G539E | Missense Mutation (SNP) | VAF 89/424 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.071); catalogued as COSV70192796; called by muse, mutect2, varscan2
- CR1 | c.2282G>A p.R761K | Missense Mutation (SNP) | VAF 72/310 reads (23%) | SIFT tolerated (0.88); PolyPhen benign (0.036); catalogued as rs1215770381, COSV100887666; called by muse, mutect2, varscan2
- CSMD1 | c.4429G>A p.E1477K (on ENST00000520002; = p.E1476K on NM_033225.6) | Missense Mutation (SNP) | VAF 83/364 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV59326169; called by muse, varscan2
- CSMD2 | c.5920G>A p.E1974K | Missense Mutation (SNP) | VAF 45/286 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.217); catalogued as COSV53968242; called by muse, mutect2, varscan2
- CWC22 | c.29C>T p.P10L | Missense Mutation (SNP) | VAF 54/293 reads (18%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.006); catalogued as rs1163667396; called by muse, mutect2, varscan2
- CYLC2 | c.179C>T p.S60F | Missense Mutation (SNP) | VAF 74/278 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.043); catalogued as COSV100872446; called by muse, mutect2, varscan2
- DGAT2L6 | c.685G>A p.E229K | Missense Mutation (SNP) | VAF 47/420 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as rs369585641, COSV60717250; called by muse, mutect2, varscan2
- DISP3 | c.1033C>T p.P345S | Missense Mutation (SNP) | VAF 133/412 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53822416; called by muse, mutect2, varscan2
- DNAH1 | c.12001G>A p.E4001K | Missense Mutation (SNP) | VAF 74/397 reads (19%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV56242138; called by muse, mutect2, varscan2
- DNAH17 | c.6600G>A p.W2200* | Nonsense Mutation (SNP) | VAF 85/430 reads (20%) | catalogued as COSV101102287; called by muse, mutect2, varscan2
- DOCK3 | c.1153C>T p.R385C | Missense Mutation (SNP) | VAF 31/253 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.677); catalogued as rs587776362, COSV56514458; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DOCK3 | c.5078G>A p.G1693E | Missense Mutation (SNP) | VAF 132/473 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.954); catalogued as COSV56532348; called by muse, mutect2, varscan2
- DSCAM | c.1016G>A p.G339E | Missense Mutation (SNP) | VAF 110/421 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV68031995; called by muse, mutect2, varscan2
- DSN1 | c.340C>T p.H114Y | Missense Mutation (SNP) | VAF 68/318 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs371293513; called by muse, mutect2, varscan2
- DSP | c.1040T>C p.I347T | Missense Mutation (SNP) | VAF 75/311 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757208743; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DYNLRB2 | c.172C>T p.R58C | Missense Mutation (SNP) | VAF 121/461 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs751931828, COSV58416178; called by muse, mutect2, varscan2
- FAM53A | c.853C>T p.P285S | Missense Mutation (SNP) | VAF 95/708 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57402633; called by muse, mutect2, varscan2
- FOXO4 | c.1048G>A p.E350K | Missense Mutation (SNP) | VAF 138/650 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0.024); catalogued as COSV100447045; called by muse, mutect2, varscan2
- FYB1 | c.176C>T p.S59F | Missense Mutation (SNP) | VAF 130/601 reads (22%) | SIFT tolerated (0.69); PolyPhen benign (0.365); catalogued as rs367990856; called by muse, mutect2, varscan2
- GLRA1 | c.140G>A p.G47E | Missense Mutation (SNP) | VAF 71/374 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV51028852; called by muse, mutect2, varscan2
- GRIN3A | c.1301C>T p.S434L | Missense Mutation (SNP) | VAF 38/194 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.313); catalogued as rs868754210; called by muse, varscan2
- GUCY2C | c.3048G>A p.V1016= | Splice Region (SNP) | VAF 50/277 reads (18%) | catalogued as COSV53788551; called by muse, mutect2, varscan2
- H6PD | c.1568C>T p.S523F | Missense Mutation (SNP) | VAF 134/816 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.034); catalogued as COSV66231364; called by muse, mutect2, varscan2
- HECW1 | c.1945G>A p.D649N | Missense Mutation (SNP) | VAF 199/772 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.014); catalogued as rs769155947, COSV67840542; called by muse, mutect2, varscan2
- HEXD | c.329C>T p.S110F | Missense Mutation (SNP) | VAF 84/521 reads (16%) | SIFT tolerated (0.72); PolyPhen benign (0.001); catalogued as rs1230330469; called by muse, mutect2, varscan2
- HPSE2 | c.893G>A p.R298K | Missense Mutation (SNP) | VAF 14/488 reads (3%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.982); catalogued as COSV65191717; called by muse, mutect2
- HRH1 | c.35A>G p.D12G | Missense Mutation (SNP) | VAF 77/405 reads (19%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.007); catalogued as rs1373011918; called by muse, mutect2, varscan2
- HTR2C | c.446C>T p.S149L | Missense Mutation (SNP) | VAF 144/592 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1556468166, COSV52204453; called by muse, mutect2, varscan2
- IARS2 | c.856A>G p.I286V | Missense Mutation (SNP) | VAF 81/285 reads (28%) | SIFT tolerated (0.51); PolyPhen benign (0.005); catalogued as COSV56965168; called by muse, mutect2, varscan2
- IGKV3-15 | c.302A>C p.E101A | Missense Mutation (SNP) | VAF 71/805 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.246); catalogued as rs772461284; called by muse, mutect2
- IL18R1 | c.796G>C p.E266Q | Missense Mutation (SNP) | VAF 36/173 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0.121); catalogued as COSV52123089; called by muse, mutect2, varscan2
- IL6ST | c.79C>T p.P27S | Missense Mutation (SNP) | VAF 47/200 reads (24%) | SIFT tolerated (0.9); PolyPhen benign (0.013); catalogued as COSV61141019; called by muse, mutect2, varscan2
- INSR | c.3620C>T p.S1207F | Missense Mutation (SNP) | VAF 82/343 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57167060; called by muse, mutect2, varscan2
- IRAG1 | c.2476G>A p.E826K | Missense Mutation (SNP) | VAF 72/381 reads (19%) | SIFT tolerated (0.43); PolyPhen benign (0.007); catalogued as rs778376788; called by muse, mutect2, varscan2
- ISM2 | c.1133C>T p.T378I (on ENST00000342219 / NM_199296.3; = p.P263S on NM_182509.4) | Missense Mutation (SNP) | VAF 92/349 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs774426050, COSV53634893; called by muse, mutect2, varscan2
- JPH1 | c.670C>T p.R224C | Missense Mutation (SNP) | VAF 106/493 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs1393912487, COSV60609000; called by muse, mutect2, varscan2
- JPH2 | c.1459C>T p.P487S | Missense Mutation (SNP) | VAF 168/678 reads (25%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as rs919085890; called by muse, mutect2, varscan2
- KCNB1 | c.1508C>T p.S503F | Missense Mutation (SNP) | VAF 107/497 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as COSV65566630; called by muse, mutect2, varscan2
- KIDINS220 | c.3916C>T p.R1306C | Missense Mutation (SNP) | VAF 89/389 reads (23%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.007); catalogued as rs770356254; called by muse, mutect2, varscan2
- KIF2B | c.656G>A p.R219K | Missense Mutation (SNP) | VAF 158/604 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1187712795; called by muse, mutect2
- KL | c.1759G>A p.E587K | Missense Mutation (SNP) | VAF 48/595 reads (8%) | SIFT tolerated (0.77); PolyPhen benign (0.012); catalogued as COSV66309913; called by muse, mutect2
- LILRB4 | c.934G>A p.G312R | Missense Mutation (SNP) | VAF 25/220 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs146946125, COSV99553745; called by muse, mutect2, varscan2
- LRP4 | c.4144C>T p.P1382S | Missense Mutation (SNP) | VAF 92/485 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0.011); catalogued as rs765240067, COSV66137009; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LRP8 | c.1306G>A p.D436N | Missense Mutation (SNP) | VAF 117/459 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0.116); catalogued as rs758343793; called by muse, mutect2, varscan2
- LRRC37A | c.4335G>A p.W1445* | Nonsense Mutation (SNP) | VAF 80/755 reads (11%) | catalogued as rs1373559925; called by muse, mutect2, varscan2
- LRRCC1 | c.769C>T p.P257S | Missense Mutation (SNP) | VAF 89/386 reads (23%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs779358210; called by muse, mutect2, varscan2
- MAGEC3 | c.469C>T p.P157S | Missense Mutation (SNP) | VAF 125/570 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as rs559021818, COSV53580931; called by muse, mutect2, varscan2
- MDN1 | c.10436C>T p.S3479L | Missense Mutation (SNP) | VAF 103/514 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV65521034; called by muse, mutect2, varscan2
- MUC16 | c.28838C>T p.P9613L | Missense Mutation (SNP) | VAF 133/528 reads (25%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.056); catalogued as COSV67445682; called by muse, mutect2, varscan2
- MUC16 | c.20171C>T p.S6724F | Missense Mutation (SNP) | VAF 79/438 reads (18%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.036); catalogued as COSV67447634; called by muse, mutect2, varscan2
- MUC16 | c.14399C>T p.S4800L | Missense Mutation (SNP) | VAF 68/445 reads (15%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.943); catalogued as rs777222644; called by muse, mutect2, varscan2
- MUC16 | c.7208C>T p.S2403F | Missense Mutation (SNP) | VAF 113/459 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.919); catalogued as rs1357636577, COSV67447684; called by muse, mutect2, varscan2
- MUC16 | c.3871C>T p.H1291Y | Missense Mutation (SNP) | VAF 140/503 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.19); catalogued as COSV67451827; called by muse, mutect2, varscan2
- MUC22 | c.976G>A p.E326K | Missense Mutation (SNP) | VAF 182/795 reads (23%) | SIFT deleterious (0); catalogued as rs558027735; called by muse, mutect2, varscan2
- MYO15B | c.4651C>T p.P1551S | Missense Mutation (SNP) | VAF 119/465 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.273); catalogued as rs963432252; called by muse, mutect2, varscan2
- NLRC3 | c.1159G>A p.E387K | Missense Mutation (SNP) | VAF 142/600 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.038); catalogued as rs753539558, COSV57090642; called by muse, mutect2, varscan2
- NLRP14 | c.2405G>A p.G802E | Missense Mutation (SNP) | VAF 101/439 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1167290724; called by muse, mutect2, varscan2
- NOS1 | c.1890G>A p.W630* | Nonsense Mutation (SNP) | VAF 105/301 reads (35%) | catalogued as COSV57620278; called by muse, mutect2, varscan2
- OR1B1 | c.155C>T p.S52F | Missense Mutation (SNP) | VAF 98/501 reads (20%) | SIFT tolerated (0.5); PolyPhen benign (0.035); catalogued as rs1293680550; called by muse, mutect2, varscan2
- OR2J3 | c.803G>A p.G268E | Missense Mutation (SNP) | VAF 119/472 reads (25%) | SIFT tolerated (0.23); PolyPhen benign (0.011); catalogued as rs1308459445, COSV101013667, COSV65848677, COSV99058513; called by muse, mutect2, varscan2
- OR4C6 | c.407C>T p.P136L | Missense Mutation (SNP) | VAF 117/494 reads (24%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.266); catalogued as COSV58604141; called by muse, mutect2, varscan2
- OR4L1 | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 92/293 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.02); catalogued as COSV59850439; called by muse, mutect2, varscan2
- OR51D1 | c.697C>T p.L233F | Missense Mutation (SNP) | VAF 134/574 reads (23%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.722); catalogued as rs1277834226, COSV62914475, COSV62914692; called by muse, mutect2, varscan2
- OR51S1 | c.913G>A p.E305K | Missense Mutation (SNP) | VAF 83/445 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.556); catalogued as COSV59058146; called by muse, mutect2, varscan2
- OTC | c.68G>A p.R23Q | Missense Mutation (SNP) | VAF 99/355 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as rs148660170; called by muse, mutect2, varscan2
- P2RY10 | c.594G>A p.M198I | Missense Mutation (SNP) | VAF 127/495 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.062); catalogued as COSV50681186; called by muse, mutect2, varscan2
- PBRM1 | c.28T>C p.S10P | Missense Mutation (SNP) | VAF 80/359 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV56304030; called by muse, mutect2, varscan2
- PCDH15 | c.4828G>A p.E1610K | Missense Mutation (SNP) | VAF 140/455 reads (31%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.005); catalogued as COSV100227257; called by muse, mutect2, varscan2
- PCDH19 | c.3344G>A p.G1115E (on ENST00000373034 / NM_001184880.2; = p.G1067E on NM_020766.3) | Missense Mutation (SNP) | VAF 133/635 reads (21%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.998); catalogued as COSV55260106; called by muse, mutect2, varscan2
- PCDHA10 | c.1280G>A p.R427Q | Missense Mutation (SNP) | VAF 134/696 reads (19%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.087); catalogued as COSV56516220; called by muse, mutect2, varscan2
- PCDHA11 | c.806G>A p.R269Q | Missense Mutation (SNP) | VAF 100/418 reads (24%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.015); catalogued as rs781996593, COSV56502100; called by muse, mutect2, varscan2
- PCDHB11 | c.151G>A p.D51N | Missense Mutation (SNP) | VAF 139/452 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.259); catalogued as rs139793689; called by muse, mutect2, varscan2
- PCDHB15 | c.554G>A p.R185Q | Missense Mutation (SNP) | VAF 89/496 reads (18%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.087); catalogued as COSV50889694, COSV50909484; called by muse, mutect2, varscan2
- PCDHB6 | c.871G>A p.E291K | Missense Mutation (SNP) | VAF 90/420 reads (21%) | SIFT tolerated, low confidence (0.16); PolyPhen probably damaging (0.996); catalogued as COSV50691822; called by muse, mutect2, varscan2
- PCSK5 | c.386C>T p.P129L | Missense Mutation (SNP) | VAF 71/310 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.567); catalogued as rs865948595; called by muse, mutect2, varscan2
- PENK | c.342G>A p.M114I | Missense Mutation (SNP) | VAF 130/420 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0.033); catalogued as COSV59240674; called by muse, mutect2, varscan2
- PLEK | c.146C>T p.P49L | Missense Mutation (SNP) | VAF 62/362 reads (17%) | SIFT tolerated (1); PolyPhen probably damaging (1); catalogued as rs147637803; called by muse, mutect2, varscan2
- POU6F2 | c.1043C>T p.P348L | Missense Mutation (SNP) | VAF 138/372 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101302554; called by muse, mutect2, varscan2
- PPM1H | c.979G>A p.G327R | Missense Mutation (SNP) | VAF 89/330 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV57370590; called by muse, mutect2, varscan2
- PRR12 | c.424G>A p.G142S (on ENST00000615927; = p.G963S on NM_020719.3) | Missense Mutation (SNP) | VAF 59/816 reads (7%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs746044633; called by muse, mutect2
- PRR36 | c.1129C>T p.P377S | Missense Mutation (SNP) | VAF 140/559 reads (25%) | SIFT tolerated (0.35); catalogued as rs1048385280; called by muse, mutect2, varscan2
- PTGIS | c.254C>T p.A85V | Missense Mutation (SNP) | VAF 102/415 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as rs777329256, COSV54839735; called by muse, mutect2, varscan2
- PTPRK | c.4075G>A p.E1359K (on ENST00000368215 / NM_001291984.2; = p.E1360K on NM_002844.4) | Missense Mutation (SNP) | VAF 127/565 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.053); catalogued as COSV63895130; called by muse, mutect2, varscan2
- RGPD4 | c.5243G>A p.G1748E | Missense Mutation (SNP) | VAF 63/297 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.647); catalogued as COSV61749649; called by muse, mutect2, varscan2
- RHPN1 | c.1766C>T p.S589L | Missense Mutation (SNP) | VAF 117/448 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.127); catalogued as rs758430332; called by muse, mutect2, varscan2
- RIMS4 | c.170G>A p.R57Q | Missense Mutation (SNP) | VAF 121/683 reads (18%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.684); catalogued as rs1221707291; called by muse, mutect2, varscan2
- RING1 | c.764C>T p.P255L | Missense Mutation (SNP) | VAF 117/542 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.092); catalogued as rs769288897; called by muse, mutect2, varscan2
- RP1 | c.668G>A p.G223E | Missense Mutation (SNP) | VAF 81/361 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55109741, COSV99606467; called by muse, mutect2, varscan2
- RP1L1 | c.5282G>A p.G1761E | Missense Mutation (SNP) | VAF 87/524 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV66752440; called by muse, varscan2
- RTN1 | c.1577C>T p.P526L | Missense Mutation (SNP) | VAF 122/480 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.026); catalogued as rs769277478; called by muse, mutect2, varscan2
- RTN1 | c.1576C>T p.P526S | Missense Mutation (SNP) | VAF 121/479 reads (25%) | SIFT tolerated (0.71); PolyPhen benign (0.003); catalogued as rs1185946773; called by muse, mutect2, varscan2
- RYR1 | c.7590G>A p.M2530I | Missense Mutation (SNP) | VAF 34/344 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.028); catalogued as rs1159462432; called by muse, mutect2
- SCEL | c.38G>A p.G13E | Missense Mutation (SNP) | VAF 45/276 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as COSV62994572; called by muse, mutect2, varscan2
- SCN11A | c.4367C>T p.P1456L | Missense Mutation (SNP) | VAF 62/309 reads (20%) | SIFT tolerated (0.63); PolyPhen benign (0.005); catalogued as COSV56572261; called by muse, mutect2, varscan2
- SCN5A | c.73G>A p.E25K | Missense Mutation (SNP) | VAF 85/502 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.981); catalogued as rs747251132, COSV60067355; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCN7A | c.3340G>A p.E1114K | Missense Mutation (SNP) | VAF 66/362 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0.094); catalogued as rs375736846; called by muse, varscan2
- SEMA6D | c.3170C>T p.S1057F (on ENST00000316364 / NM_153618.2; = p.S995F on NM_020858.2) | Missense Mutation (SNP) | VAF 69/422 reads (16%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.555); catalogued as rs1184451050; called by muse, mutect2, varscan2
- SIGLEC11 | c.1355C>T p.S452F | Missense Mutation (SNP) | VAF 222/536 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.043); catalogued as rs777762992; called by muse, mutect2, varscan2
- SIGLEC12 | c.1759G>A p.E587K (on ENST00000291707 / NM_053003.4; = p.E469K on NM_033329.2) | Missense Mutation (SNP) | VAF 32/477 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.04); catalogued as rs1463441495; called by muse, mutect2
- SLC22A10 | c.644C>T p.S215L | Missense Mutation (SNP) | VAF 65/279 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.012); catalogued as COSV60420249; called by muse, mutect2, varscan2
- SLC27A6 | c.1172C>T p.S391F | Missense Mutation (SNP) | VAF 50/263 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52485730; called by muse, mutect2, varscan2
- SLC39A10 | c.1726C>T p.R576* | Nonsense Mutation (SNP) | VAF 53/253 reads (21%) | catalogued as COSV62767437; called by muse, mutect2, varscan2
- SLC5A6 | c.896C>T p.P299L | Missense Mutation (SNP) | VAF 45/310 reads (15%) | SIFT tolerated (1); PolyPhen probably damaging (0.951); catalogued as COSV60161559; called by muse, mutect2, varscan2
- SLFN12L | c.487C>T p.P163S (on ENST00000260908 / NM_001363830.1; = p.P181S on NM_001195790.1) | Missense Mutation (SNP) | VAF 93/479 reads (19%) | SIFT tolerated (0.81); PolyPhen benign (0.017); catalogued as COSV53469908; called by muse, mutect2, varscan2
- SP140 | c.1340C>T p.S447L | Missense Mutation (SNP) | VAF 19/227 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs1326608474, COSV59453400; called by muse, mutect2
- SPATA31D1 | c.4288G>C p.E1430Q | Missense Mutation (SNP) | VAF 19/528 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.068); catalogued as COSV100782843; called by muse, mutect2
- SPATA31E1 | c.2687G>A p.G896E | Missense Mutation (SNP) | VAF 95/451 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.853); catalogued as rs139269965; called by muse, mutect2, varscan2
- ST8SIA2 | c.536G>A p.S179N | Missense Mutation (SNP) | VAF 78/307 reads (25%) | PolyPhen benign (0.014); catalogued as rs1390727961; called by muse, mutect2, varscan2
- ST8SIA5 | c.1099C>T p.R367C | Missense Mutation (SNP) | VAF 76/271 reads (28%) | PolyPhen probably damaging (0.916); catalogued as rs1235483250, COSV100164639, COSV59331093; called by muse, mutect2, varscan2
- STON1-GTF2A1L | c.2296C>T p.Q766* | Nonsense Mutation (SNP) | VAF 67/366 reads (18%) | catalogued as rs780972742, COSV59136730, COSV59140445; called by muse, mutect2, varscan2
- SYT1 | c.599G>A p.R200Q | Missense Mutation (SNP) | VAF 76/283 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV54045062, COSV99697600; called by muse, mutect2, varscan2
- TAT | c.95G>A p.G32E | Missense Mutation (SNP) | VAF 109/522 reads (21%) | SIFT tolerated (0.48); PolyPhen benign (0.006); catalogued as rs890124917, COSV63532574; called by muse, mutect2, varscan2
- TIMM9 | c.17C>T p.P6L | Missense Mutation (SNP) | VAF 53/165 reads (32%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV53622343; called by muse, mutect2, varscan2
- TLR10 | c.98A>G p.N33S | Missense Mutation (SNP) | VAF 32/878 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.546); catalogued as rs1331700164; called by muse, mutect2
- TMC1 | c.857G>A p.G286E | Missense Mutation (SNP) | VAF 103/361 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as rs1296250761, COSV52785081; called by muse, mutect2, varscan2
- TRA2B | c.346C>T p.P116S | Missense Mutation (SNP) | VAF 88/344 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.254); catalogued as COSV52026013; called by muse, mutect2
- TTC34 | c.1225G>A p.D409N | Missense Mutation (SNP) | VAF 14/406 reads (3%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.737); catalogued as rs931383928; called by muse, mutect2
- TTN | c.102758G>A p.G34253E (on ENST00000591111; = p.G26829E on NM_003319.4) | Missense Mutation (SNP) | VAF 48/210 reads (23%) | PolyPhen probably damaging (1); catalogued as rs867480007, COSV60105851; called by muse, mutect2, varscan2
- TTN | c.102052G>A p.D34018N (on ENST00000591111; = p.D26594N on NM_003319.4) | Missense Mutation (SNP) | VAF 106/426 reads (25%) | PolyPhen benign (0.025); catalogued as rs878992336; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.42661C>T p.P14221S (on ENST00000591111; = p.P6797S on NM_003319.4) | Missense Mutation (SNP) | VAF 51/263 reads (19%) | PolyPhen probably damaging (0.998); catalogued as rs879096040; called by muse, mutect2, varscan2
- TTN | c.33037C>T p.P11013S (on ENST00000591111; = p.P10086S on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 52/345 reads (15%) | PolyPhen benign (0.022); catalogued as COSV60222920; called by muse, mutect2, varscan2
- TTN | c.22229G>A p.G7410E (on ENST00000591111; = p.G6483E on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 57/338 reads (17%) | PolyPhen probably damaging (1); catalogued as rs763907919, COSV59986301; called by muse, mutect2, varscan2
- TXNDC2 | c.1192C>T p.P398S (on ENST00000306084 / NM_001098529.2; = p.P331S on NM_032243.6) | Missense Mutation (SNP) | VAF 164/500 reads (33%) | SIFT tolerated (0.45); PolyPhen benign (0.01); catalogued as rs1334856475; called by muse, mutect2, varscan2
- UGT1A10 | c.220G>A p.V74M | Missense Mutation (SNP) | VAF 72/344 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.363); catalogued as rs371744958; called by muse, mutect2, varscan2
- VWA5B1 | c.3182C>T p.A1061V (on ENST00000375079; = p.A1056V on NM_001039500.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 73/268 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs61742171; called by muse, mutect2, varscan2
- WDR49 | c.1240G>A p.E414K (on ENST00000308378 / NM_001366158.1; = p.E755K on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 100/461 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.588); catalogued as COSV57711432; called by muse, mutect2, varscan2
- ZAN | c.2203C>T p.P735S | Missense Mutation (SNP) | VAF 182/517 reads (35%) | SIFT tolerated (0.61); PolyPhen probably damaging (0.998); catalogued as rs376016003; called by muse, mutect2, varscan2
- ZNF117 | c.1090G>A p.G364R | Missense Mutation (SNP) | VAF 133/397 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.124); catalogued as rs1471270990; called by muse, mutect2, varscan2
- ZNF185 | c.970G>A p.D324N | Missense Mutation (SNP) | VAF 19/607 reads (3%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs1556877521; called by muse, mutect2
- ZNF284 | c.155C>T p.S52F | Missense Mutation (SNP) | VAF 31/299 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV69690796; called by muse, mutect2
- ZNF556 | c.1169G>A p.R390K | Missense Mutation (SNP) | VAF 132/433 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.082); catalogued as COSV100298750; called by muse, mutect2, varscan2
- ZNF560 | c.1390G>A p.E464K | Missense Mutation (SNP) | VAF 137/542 reads (25%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs545411097, COSV56866806; called by muse, mutect2, varscan2
- ZNF594 | c.202G>A p.E68K | Missense Mutation (SNP) | VAF 105/436 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.012); catalogued as COSV101280447; called by muse, mutect2, varscan2
- ZNF711 | c.1087G>A p.E363K | Missense Mutation (SNP) | VAF 67/318 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.381); catalogued as rs867719576, COSV52153480; called by muse, mutect2, varscan2
- ZNF844 | c.1132C>T p.R378C | Missense Mutation (SNP) | VAF 61/331 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.057); catalogued as rs571606689, COSV71518597; called by muse, mutect2, varscan2
- AC011005.1 | c.800_801delinsT p.P267Lfs*59 | Frame Shift Del (DEL) | VAF 172/525 reads (33%) | called by pindel, varscan2*
- ADGB | c.130A>G p.K44E | Missense Mutation (SNP) | VAF 76/342 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.257); called by muse, mutect2, varscan2
- AGL | c.3010C>T p.P1004S | Missense Mutation (SNP) | VAF 112/960 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AKAP3 | c.1946C>T p.A649V | Missense Mutation (SNP) | VAF 87/388 reads (22%) | SIFT tolerated (0.39); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- ALS2CL | c.2096C>T p.T699I | Missense Mutation (SNP) | VAF 19/548 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ANKAR | c.3061G>A p.D1021N | Missense Mutation (SNP) | VAF 37/323 reads (11%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ANKRD11 | c.2108T>G p.M703R | Missense Mutation (SNP) | VAF 24/426 reads (6%) | SIFT tolerated (0.37); PolyPhen benign (0.031); called by muse, mutect2
- AQP12A | c.517C>T p.P173S | Missense Mutation (SNP) | VAF 24/249 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ARHGAP29 | c.1145T>C p.V382A | Missense Mutation (SNP) | VAF 45/491 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.019); called by muse, mutect2
- ARHGEF38 | c.895G>A p.D299N | Missense Mutation (SNP) | VAF 39/154 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); called by muse, mutect2, varscan2
- BCORL1 | c.1843C>T p.P615S | Missense Mutation (SNP) | VAF 126/602 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- BICRA | c.4463C>T p.S1488F | Missense Mutation (SNP) | VAF 123/647 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- BTBD8 | c.348G>A p.Q116= | Splice Region (SNP) | VAF 29/100 reads (29%) | called by muse, mutect2, varscan2
- C16orf72 | c.518C>T p.S173L | Missense Mutation (SNP) | VAF 79/454 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.265); called by muse, mutect2, varscan2
- C1orf94 | c.1490C>T p.A497V (on ENST00000488417 / NM_001134734.2; = p.A307V on NM_032884.5) | Missense Mutation (SNP) | VAF 90/454 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- CACNA1E | c.2945G>A p.R982K | Missense Mutation (SNP) | VAF 43/190 reads (23%) | SIFT tolerated (0.52); PolyPhen benign (0); called by muse, mutect2, varscan2
- CC2D2A | c.388C>G p.R130G | Missense Mutation (SNP) | VAF 317/545 reads (58%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.372); called by muse, mutect2, varscan2
- CDH16 | c.1102T>A p.S368T | Missense Mutation (SNP) | VAF 95/422 reads (23%) | SIFT tolerated (0.95); PolyPhen benign (0.108); called by muse, mutect2, varscan2
- CDH23 | c.2271del p.T759Lfs*6 | Frame Shift Del (DEL) | VAF 78/347 reads (22%) | called by mutect2, pindel, varscan2
- CDH8 | c.1882T>A p.L628I | Missense Mutation (SNP) | VAF 91/331 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- CDH8 | c.1051T>A p.Y351N | Missense Mutation (SNP) | VAF 70/318 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CEP250 | c.343G>A p.E115K | Missense Mutation (SNP) | VAF 63/311 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- CFAP221 | c.775C>T p.P259S | Missense Mutation (SNP) | VAF 54/319 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CFAP299 | c.476G>A p.S159N | Missense Mutation (SNP) | VAF 21/166 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CNTRL | c.3757G>A p.G1253S | Missense Mutation (SNP) | VAF 115/573 reads (20%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- COL21A1 | c.2366C>T p.S789L | Missense Mutation (SNP) | VAF 69/295 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CPNE7 | c.1449C>G p.Y483* | Nonsense Mutation (SNP) | VAF 148/620 reads (24%) | called by muse, mutect2, varscan2
- CRACDL | c.1874C>T p.A625V | Missense Mutation (SNP) | VAF 92/488 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0.072); called by muse, varscan2
- CSTF2T | c.1051C>A p.P351T | Missense Mutation (SNP) | VAF 119/414 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CYP2C8 | c.109C>T p.P37S | Missense Mutation (SNP) | VAF 72/432 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- DLGAP3 | c.1209T>G p.D403E | Missense Mutation (SNP) | VAF 93/535 reads (17%) | SIFT tolerated (0.35); PolyPhen benign (0.224); called by muse, mutect2, varscan2
- DLGAP3 | c.1097A>G p.H366R | Missense Mutation (SNP) | VAF 90/394 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.251); called by muse, mutect2, varscan2
- DNAH11 | c.8455A>G p.N2819D | Missense Mutation (SNP) | VAF 199/539 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DNAH5 | c.1688A>G p.Q563R | Missense Mutation (SNP) | VAF 71/326 reads (22%) | SIFT tolerated (0.35); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DNAH8 | c.838G>A p.E280K | Missense Mutation (SNP) | VAF 61/265 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- DNAH8 | c.10208G>A p.R3403K | Missense Mutation (SNP) | VAF 113/465 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DNMBP | c.996A>T p.L332F | Missense Mutation (SNP) | VAF 20/472 reads (4%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0); called by muse, mutect2
- DPYD | c.449T>G p.I150S | Missense Mutation (SNP) | VAF 89/835 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DSP | c.8522C>T p.S2841F | Missense Mutation (SNP) | VAF 87/417 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- EDC3 | c.761A>G p.E254G | Missense Mutation (SNP) | VAF 62/415 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- EFR3A | c.883G>A p.E295K | Missense Mutation (SNP) | VAF 16/435 reads (4%) | SIFT tolerated (0.39); PolyPhen benign (0.062); called by muse, mutect2
- EGFLAM | c.2275A>T p.I759F | Missense Mutation (SNP) | VAF 58/294 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- EVC | c.451C>T p.Q151* | Nonsense Mutation (SNP) | VAF 117/901 reads (13%) | called by muse, mutect2, varscan2
- FAAP100 | c.1748C>T p.P583L | Missense Mutation (SNP) | VAF 105/632 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.892); called by muse, mutect2, varscan2
- FAM135B | c.3293C>T p.A1098V | Missense Mutation (SNP) | VAF 25/155 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- FANCE | c.187T>A p.L63M | Missense Mutation (SNP) | VAF 104/534 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- FAT3 | c.5181G>T p.K1727N | Missense Mutation (SNP) | VAF 65/245 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.697); called by muse, mutect2, varscan2
- FBXO30 | c.1052T>C p.V351A | Missense Mutation (SNP) | VAF 105/456 reads (23%) | SIFT tolerated (0.61); PolyPhen benign (0); called by muse, mutect2, varscan2
- FJX1 | c.187C>T p.P63S | Missense Mutation (SNP) | VAF 153/581 reads (26%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- FLT3 | c.977G>C p.G326A | Missense Mutation (SNP) | VAF 115/496 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- FRMPD2 | c.3599G>A p.S1200N | Missense Mutation (SNP) | VAF 59/294 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- GLYATL3 | c.268G>A p.E90K | Missense Mutation (SNP) | VAF 82/374 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- GUCY2F | c.2875G>A p.D959N | Missense Mutation (SNP) | VAF 126/609 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- HECW1 | c.1100G>A p.S367N | Missense Mutation (SNP) | VAF 196/646 reads (30%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- HERC1 | c.13792C>T p.L4598F | Missense Mutation (SNP) | VAF 40/672 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- HRC | c.1086G>A p.W362* | Nonsense Mutation (SNP) | VAF 79/638 reads (12%) | called by muse, mutect2, varscan2
- HRC | c.1085G>A p.W362* | Nonsense Mutation (SNP) | VAF 81/642 reads (13%) | called by muse, mutect2, varscan2
- HS3ST4 | c.1243C>T p.R415W | Missense Mutation (SNP) | VAF 134/536 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HSPA6 | c.1367A>G p.N456S | Missense Mutation (SNP) | VAF 247/504 reads (49%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- IFT172 | c.2371G>A p.E791K | Missense Mutation (SNP) | VAF 91/401 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.311); called by muse, mutect2, varscan2
- IGHV3OR16-13 | c.17G>A p.S6N | Missense Mutation (SNP) | VAF 58/203 reads (29%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- IL1B | c.323G>A p.W108* | Nonsense Mutation (SNP) | VAF 78/286 reads (27%) | called by muse, mutect2, varscan2
- KALRN | c.7723C>T p.P2575S (on ENST00000360013 / NM_001024660.4; = p.P878S on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 95/439 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KDM6A | c.2482C>T p.P828S | Missense Mutation (SNP) | VAF 137/570 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- KIDINS220 | c.1678C>T p.L560F | Missense Mutation (SNP) | VAF 66/321 reads (21%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.799); called by muse, varscan2
- KIR3DL1 | c.1158G>A p.E386= | Splice Region (SNP) | VAF 63/510 reads (12%) | called by muse, mutect2, varscan2
- KLF11 | c.413T>C p.V138A | Missense Mutation (SNP) | VAF 96/448 reads (21%) | SIFT tolerated (0.93); PolyPhen benign (0); called by muse, mutect2, varscan2
- LACTB | c.965T>C p.L322S | Missense Mutation (SNP) | VAF 54/264 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- LCN2 | c.434A>G p.K145R | Missense Mutation (SNP) | VAF 62/344 reads (18%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.549); called by muse, mutect2, varscan2
- LILRA5 | c.464G>A p.G155E | Missense Mutation (SNP) | VAF 102/793 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- LRIF1 | c.1202C>T p.S401L | Missense Mutation (SNP) | VAF 43/559 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.31); called by muse, mutect2
- LRIT1 | c.1364A>G p.N455S | Missense Mutation (SNP) | VAF 114/540 reads (21%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.475); called by muse, mutect2, varscan2
- LRP2 | c.11008G>A p.E3670K | Missense Mutation (SNP) | VAF 46/191 reads (24%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LTBP3 | c.2482G>A p.D828N | Missense Mutation (SNP) | VAF 67/279 reads (24%) | SIFT tolerated (0.77); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MARCHF1 | c.46C>T p.P16S | Missense Mutation (SNP) | VAF 115/334 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.245); called by muse, mutect2, varscan2
- MDH2 | c.710T>G p.V237G | Missense Mutation (SNP) | VAF 79/490 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- METAP2 | c.1333C>T p.P445S | Missense Mutation (SNP) | VAF 149/446 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.821); called by muse, mutect2, varscan2
- MID1 | c.1067A>T p.N356I | Missense Mutation (SNP) | VAF 121/483 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- MID2 | c.77C>T p.S26F | Missense Mutation (SNP) | VAF 20/614 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- MPO | c.821C>T p.S274F | Missense Mutation (SNP) | VAF 82/485 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); called by muse, mutect2, varscan2
- MPST | c.367C>T p.H123Y (on ENST00000341116 / NM_001369904.2; = p.H143Y on NM_021126.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 76/1266 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.018); called by muse, mutect2
- MUC16 | c.11492C>T p.S3831L | Missense Mutation (SNP) | VAF 20/538 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); called by muse, mutect2
- MUC16 | c.11063C>T p.P3688L | Missense Mutation (SNP) | VAF 94/458 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- MUC22 | c.4474G>A p.G1492S | Missense Mutation (SNP) | VAF 89/504 reads (18%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- MYH8 | c.2845G>A p.E949K | Missense Mutation (SNP) | VAF 105/383 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- MYT1L | c.2563C>T p.P855S | Missense Mutation (SNP) | VAF 79/408 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.337); called by muse, mutect2, varscan2
- NFAM1 | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 51/758 reads (7%) | SIFT tolerated, low confidence (0.24); PolyPhen possibly damaging (0.732); called by muse, mutect2
- NFKBIL1 | c.374C>T p.P125L | Missense Mutation (SNP) | VAF 95/680 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2
- NKAP | c.37G>A p.E13K | Missense Mutation (SNP) | VAF 127/544 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- NLRP2B | c.107G>A p.G36E | Missense Mutation (SNP) | VAF 60/275 reads (22%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- NLRP8 | c.2018G>A p.S673N | Missense Mutation (SNP) | VAF 38/410 reads (9%) | SIFT tolerated (0.62); PolyPhen benign (0.023); called by muse, mutect2
- NONO | c.1106G>A p.G369E | Missense Mutation (SNP) | VAF 81/366 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.792); called by muse, mutect2, varscan2
- NSD1 | c.4048C>T p.P1350S | Missense Mutation (SNP) | VAF 109/502 reads (22%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- NUSAP1 | c.367G>A p.E123K | Missense Mutation (SNP) | VAF 50/498 reads (10%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.641); called by muse, mutect2
- OBSCN | c.21259C>T p.P7087S | Missense Mutation (SNP) | VAF 225/710 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OGDHL | c.1663G>A p.E555K | Missense Mutation (SNP) | VAF 28/285 reads (10%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.811); called by muse, mutect2, varscan2
- OR56A3 | c.742C>A p.H248N | Missense Mutation (SNP) | VAF 104/512 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, varscan2
- OR6X1 | c.680C>T p.P227L | Missense Mutation (SNP) | VAF 112/318 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.588); called by muse, mutect2, varscan2
- PADI4 | c.827A>G p.N276S | Missense Mutation (SNP) | VAF 67/223 reads (30%) | SIFT tolerated (0.53); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- PATJ | c.871G>A p.D291N | Missense Mutation (SNP) | VAF 42/307 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PBX4 | c.503C>T p.P168L | Missense Mutation (SNP) | VAF 48/564 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PCDHA5 | c.160G>A p.E54K | Missense Mutation (SNP) | VAF 164/677 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.171); called by muse, mutect2, varscan2
- PCDHAC1 | c.2021G>A p.G674E | Missense Mutation (SNP) | VAF 130/569 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PDCL | c.407T>C p.F136S | Missense Mutation (SNP) | VAF 67/338 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- PDE1C | c.802C>T p.H268Y | Missense Mutation (SNP) | VAF 100/445 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- PDGFB | c.457G>A p.V153M | Missense Mutation (SNP) | VAF 48/492 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- PEX6 | c.1856A>T p.N619I | Missense Mutation (SNP) | VAF 137/488 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); called by muse, mutect2, varscan2
- PLAUR | c.719C>T p.P240L | Missense Mutation (SNP) | VAF 188/424 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PLEKHG4B | c.763G>A p.G255R (on ENST00000283426; = p.G611R on NM_052909.5) | Missense Mutation (SNP) | VAF 40/396 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PLSCR4 | c.281C>T p.S94F | Missense Mutation (SNP) | VAF 66/468 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- POLN | c.725C>T p.S242F | Missense Mutation (SNP) | VAF 216/377 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- POPDC2 | c.937C>T p.P313S | Missense Mutation (SNP) | VAF 140/570 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PPP4R3B | c.1762T>A p.L588M | Missense Mutation (SNP) | VAF 47/181 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PRKCE | c.109C>T p.L37F | Missense Mutation (SNP) | VAF 66/397 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- PTOV1 | c.290_293delinsTTG p.G97Vfs*19 | Frame Shift Del (DEL) | VAF 162/471 reads (34%) | called by pindel, varscan2*
- QRSL1 | c.679A>T p.M227L | Missense Mutation (SNP) | VAF 127/466 reads (27%) | SIFT tolerated (0.27); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- RAD54L2 | c.563G>T p.S188I | Missense Mutation (SNP) | VAF 89/397 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- RAI2 | c.1466G>A p.G489E | Missense Mutation (SNP) | VAF 126/599 reads (21%) | SIFT tolerated (0.76); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- RANBP2 | c.7062T>G p.I2354M | Missense Mutation (SNP) | VAF 91/458 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RASGRF2 | c.372G>A p.W124* | Nonsense Mutation (SNP) | VAF 11/353 reads (3%) | called by muse, mutect2
- RB1CC1 | c.2866G>A p.E956K | Missense Mutation (SNP) | VAF 102/390 reads (26%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.395); called by muse, mutect2, varscan2
- RGP1 | c.539C>T p.P180L | Missense Mutation (SNP) | VAF 117/313 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RS1 | c.130G>A p.G44R | Missense Mutation (SNP) | VAF 100/542 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.809); called by muse, mutect2, varscan2
- SATB1 | c.241G>A p.E81K | Missense Mutation (SNP) | VAF 75/374 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SCART1 | c.1706C>A p.A569D | Missense Mutation (SNP) | VAF 102/1372 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.46); called by muse, mutect2
- SDR42E2 | c.675C>T p.G225= | Splice Region (SNP) | VAF 75/315 reads (24%) | called by muse, mutect2, varscan2
- SELP | c.2041G>C p.D681H | Missense Mutation (SNP) | VAF 169/366 reads (46%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- SGSM1 | c.2561C>G p.T854R (on ENST00000400359 / NM_001039948.4; = p.T793R on NM_133454.3) | Missense Mutation (SNP) | VAF 118/732 reads (16%) | SIFT tolerated (0.53); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- SHANK2 | c.2425G>A p.G809S | Missense Mutation (SNP) | VAF 68/422 reads (16%) | SIFT tolerated (0.61); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SIRPG | c.1091C>T p.S364L | Missense Mutation (SNP) | VAF 94/376 reads (25%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC23A2 | c.542C>T p.S181F | Missense Mutation (SNP) | VAF 91/365 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- SLC26A9 | c.2255G>A p.G752E | Missense Mutation (SNP) | VAF 82/456 reads (18%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2
- SLC27A3 | c.857G>A p.G286E (on ENST00000271857; = p.G158E on NM_024330.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/787 reads (3%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2
- SLC39A13 | c.284C>A p.T95N | Missense Mutation (SNP) | VAF 80/370 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.015); called by muse, mutect2
- SLC44A5 | c.2114G>A p.G705E | Missense Mutation (SNP) | VAF 113/442 reads (26%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2
- SMG1 | c.6938T>C p.V2313A | Missense Mutation (SNP) | VAF 66/311 reads (21%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- SPATA20 | c.184C>T p.P62S (on ENST00000356488 / NM_001258372.1; = p.P78S on NM_022827.4) | Missense Mutation (SNP) | VAF 88/503 reads (17%) | SIFT tolerated (0.86); PolyPhen benign (0.213); called by muse, mutect2, varscan2
- SSU72P4 | c.565C>T p.H189Y | Missense Mutation (SNP) | VAF 54/698 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2
- STARD9 | c.532C>T p.H178Y | Missense Mutation (SNP) | VAF 37/199 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- STEAP2 | c.306G>A p.W102* | Nonsense Mutation (SNP) | VAF 166/353 reads (47%) | called by muse, mutect2, varscan2
- SYK | c.1797A>T p.R599S | Missense Mutation (SNP) | VAF 63/325 reads (19%) | SIFT tolerated (0.33); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- SYNE1 | c.14767G>A p.E4923K (on ENST00000367255 / NM_182961.4; = p.E4852K on NM_033071.3) | Missense Mutation (SNP) | VAF 125/479 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TAS2R5 | c.44T>C p.V15A | Missense Mutation (SNP) | VAF 163/355 reads (46%) | SIFT tolerated (0.64); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- TBX2 | c.1990C>T p.L664F | Missense Mutation (SNP) | VAF 172/708 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- TENM1 | c.2201G>A p.G734D | Missense Mutation (SNP) | VAF 16/560 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- TEX11 | c.457G>A p.E153K (on ENST00000344304; = p.E138K on NM_031276.3) | Missense Mutation (SNP) | VAF 52/265 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TEX13A | c.457T>C p.W153R | Missense Mutation (SNP) | VAF 51/219 reads (23%) | SIFT tolerated (0.37); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- TEX15 | c.2879C>T p.S960F (on ENST00000256246; = p.S1343F on NM_001350162.2) | Missense Mutation (SNP) | VAF 88/341 reads (26%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TEX2 | c.485C>T p.S162F | Missense Mutation (SNP) | VAF 77/509 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- THBS2 | c.590C>T p.A197V | Missense Mutation (SNP) | VAF 60/288 reads (21%) | SIFT tolerated (0.78); PolyPhen benign (0); called by muse, mutect2, varscan2
- THSD7A | c.2836C>T p.H946Y | Missense Mutation (SNP) | VAF 140/419 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TLR7 | c.2882A>T p.Y961F | Missense Mutation (SNP) | VAF 138/544 reads (25%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.651); called by muse, mutect2, varscan2
- TMEM50A | c.289C>T p.L97F | Missense Mutation (SNP) | VAF 14/306 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.656); called by muse, mutect2
- TNXB | c.6068C>T p.P2023L (on ENST00000647633; = p.P1776L on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 79/451 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- TOX3 | c.925G>A p.E309K | Missense Mutation (SNP) | VAF 69/288 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TPX2 | c.768_792delinsT p.K256_T264delinsN | In Frame Del (DEL) | VAF 72/490 reads (15%) | called by pindel, varscan2*
- TRBV7-1 | c.191T>G p.F64C | Missense Mutation (SNP) | VAF 20/396 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2
- TSPYL2 | c.1738G>A p.D580N | Missense Mutation (SNP) | VAF 48/902 reads (5%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.977); called by muse, mutect2
- TTN | c.72682G>A p.G24228R (on ENST00000591111; = p.G16804R on NM_003319.4) | Missense Mutation (SNP) | VAF 47/346 reads (14%) | PolyPhen benign (0.219); called by muse, mutect2, varscan2
- TTN | c.54365C>T p.A18122V (on ENST00000591111; = p.A10698V on NM_003319.4) | Missense Mutation (SNP) | VAF 92/430 reads (21%) | PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TTN | c.44698G>A p.E14900K (on ENST00000591111; = p.E7476K on NM_003319.4) | Missense Mutation (SNP) | VAF 56/272 reads (21%) | PolyPhen possibly damaging (0.6); called by muse, mutect2, varscan2
- TTN | c.29366C>T p.A9789V (on ENST00000591111; = p.A8862V on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 74/429 reads (17%) | PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- UFM1 | c.232C>T p.P78S | Missense Mutation (SNP) | VAF 52/304 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.839); called by muse, mutect2, varscan2
- UGT2A3 | c.914T>A p.F305Y | Missense Mutation (SNP) | VAF 93/348 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- USP54 | c.3125T>C p.I1042T | Missense Mutation (SNP) | VAF 72/480 reads (15%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0); called by muse, varscan2
- USP9X | c.5143G>A p.G1715R | Missense Mutation (SNP) | VAF 16/428 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2
- VWA5B1 | c.139G>A p.G47S | Missense Mutation (SNP) | VAF 59/203 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- WDR19 | c.2143G>A p.G715R | Missense Mutation (SNP) | VAF 70/372 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- WDR72 | c.2251G>A p.A751T | Missense Mutation (SNP) | VAF 89/389 reads (23%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZC3H15 | c.96_97insTT p.N33Lfs*29 | Frame Shift Ins (INS) | VAF 33/249 reads (13%) | called by mutect2, pindel, varscan2
- ZCCHC12 | c.863C>T p.P288L | Missense Mutation (SNP) | VAF 108/478 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- ZDHHC15 | c.35G>A p.G12E | Missense Mutation (SNP) | VAF 14/466 reads (3%) | SIFT tolerated (0.27); PolyPhen benign (0.347); called by muse, mutect2
- ZDHHC8 | c.1606C>T p.P536S | Missense Mutation (SNP) | VAF 323/908 reads (36%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- ZFHX4 | c.2231C>A p.P744Q | Missense Mutation (SNP) | VAF 125/533 reads (23%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.775); called by muse, mutect2, varscan2
- ZNF292 | c.3457T>C p.F1153L | Missense Mutation (SNP) | VAF 108/414 reads (26%) | SIFT tolerated (0.9); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF479 | c.977G>T p.R326M | Missense Mutation (SNP) | VAF 69/609 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.392); called by muse, mutect2, varscan2
- ZNF541 | c.1853C>T p.P618L | Missense Mutation (SNP) | VAF 43/712 reads (6%) | SIFT tolerated (0.27); PolyPhen benign (0.306); called by muse, mutect2
- ZNF569 | c.1100C>T p.S367F | Missense Mutation (SNP) | VAF 28/534 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2
- ACO2 | c.1623G>A p.Q541= | Silent (SNP) | VAF 91/976 reads (9%) | called by muse, mutect2
- ACSM1 | c.1644G>A p.R548= | Silent (SNP) | VAF 27/122 reads (22%) | called by muse, mutect2, varscan2
- ACSM5 | c.1296C>T p.F432= | Silent (SNP) | VAF 77/343 reads (22%) | called by muse, mutect2, varscan2
- ADGRF2 | c.1518C>T p.S506= (on ENST00000296862 / NM_001368115.2; = p.S438= on NM_153839.7) | Silent (SNP) | VAF 108/484 reads (22%) | catalogued as rs777079474; called by muse, mutect2, varscan2
- AGAP3 | c.1311C>A p.A437= (on ENST00000622464; = p.A473= on NM_031946.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 286/589 reads (49%) | catalogued as rs1355240015; called by muse, mutect2, varscan2
- AKT2 | c.81C>T p.F27= | Silent (SNP) | VAF 76/354 reads (21%) | called by muse, mutect2, varscan2
- ANKLE2 | c.792C>T p.S264= | Silent (SNP) | VAF 116/447 reads (26%) | catalogued as COSV100513911; called by muse, mutect2, varscan2
- ARMC4 | c.2634C>T p.S878= | Silent (SNP) | VAF 75/237 reads (32%) | catalogued as rs1164217391; called by muse, mutect2, varscan2
- ARPC4 | c.174G>A p.K58= | Silent (SNP) | VAF 93/386 reads (24%) | called by muse, mutect2, varscan2
- ASH1L | c.5922C>T p.L1974= | Silent (SNP) | VAF 197/409 reads (48%) | called by muse, mutect2, varscan2
- ATP13A2 | c.2286G>A p.R762= | Silent (SNP) | VAF 121/408 reads (30%) | catalogued as rs758764563; called by muse, mutect2, varscan2
- AVPR1B | c.216C>T p.F72= | Silent (SNP) | VAF 138/684 reads (20%) | catalogued as rs782749281, COSV65637761; called by muse, mutect2, varscan2
- B4GALNT2 | c.1356G>A p.K452= | Silent (SNP) | VAF 17/481 reads (4%) | catalogued as rs868718164, COSV55925472; called by muse, mutect2
- BCL2L12 | c.24C>T p.F8= | Silent (SNP) | VAF 144/328 reads (44%) | catalogued as COSV55862291; called by muse, mutect2, varscan2
- BICRA | c.4464C>T p.S1488= | Silent (SNP) | VAF 122/646 reads (19%) | catalogued as rs771473550, COSV67604533; called by muse, mutect2, varscan2
- BMPER | c.1170G>A p.L390= | Silent (SNP) | VAF 108/585 reads (18%) | catalogued as COSV51820093, COSV51826567; called by muse, mutect2, varscan2
- BRINP3 | c.1005C>T p.F335= | Silent (SNP) | VAF 75/247 reads (30%) | catalogued as COSV66514613; called by muse, mutect2, varscan2
- BROX | c.1017C>T p.A339= | Silent (SNP) | VAF 60/269 reads (22%) | catalogued as COSV61799864; called by muse, mutect2, varscan2
- BTF3L4 | c.16T>C p.L6= | Silent (SNP) | VAF 100/353 reads (28%) | called by muse, mutect2, varscan2
- C10orf71 | c.1956G>A p.R652= | Silent (SNP) | VAF 17/422 reads (4%) | called by muse, mutect2
- C2orf81 | c.1494T>C p.P498= | Silent (SNP) | VAF 56/417 reads (13%) | called by muse, mutect2, varscan2
- C3 | c.399G>A p.Q133= | Silent (SNP) | VAF 71/466 reads (15%) | called by muse, mutect2, varscan2
- CAMKMT | c.927A>G p.E309= | Silent (SNP) | VAF 44/274 reads (16%) | catalogued as COSV65924316; called by muse, mutect2, varscan2
- CARD6 | c.2556C>T p.S852= | Silent (SNP) | VAF 108/445 reads (24%) | called by muse, mutect2, varscan2
- CCDC110 | c.1608G>A p.K536= | Silent (SNP) | VAF 52/184 reads (28%) | catalogued as COSV100293853; called by muse, mutect2, varscan2
- CDH8 | c.1050C>T p.S350= | Silent (SNP) | VAF 68/313 reads (22%) | catalogued as COSV100181271, COSV54901167; called by muse, mutect2, varscan2
- CDKL5 | c.384G>A p.K128= | Silent (SNP) | VAF 64/301 reads (21%) | called by muse, mutect2, varscan2
- CEACAM20 | c.1560G>A p.R520= | Silent (SNP) | VAF 51/504 reads (10%) | called by muse, mutect2
- CEP78 | c.2064C>T p.S688= (on ENST00000424347 / NM_001349840.2; = p.S704= on NM_001330691.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 34/259 reads (13%) | called by muse, mutect2, varscan2
- CLPS | c.12C>T p.I4= | Silent (SNP) | VAF 98/552 reads (18%) | catalogued as rs771434902, COSV52565768; called by muse, mutect2, varscan2
- CORO7 | c.762C>T p.S254= | Silent (SNP) | VAF 49/743 reads (7%) | catalogued as COSV52033904; called by muse, mutect2
- CREB3L3 | c.753C>T p.I251= | Silent (SNP) | VAF 56/346 reads (16%) | catalogued as COSV50195849; called by muse, mutect2, varscan2
- CRP | c.372C>T p.I124= | Silent (SNP) | VAF 185/415 reads (45%) | catalogued as rs753294711, COSV54812508; called by muse, mutect2, varscan2
- CSMD2 | c.5919G>A p.E1973= | Silent (SNP) | VAF 45/285 reads (16%) | catalogued as COSV99592777; called by muse, mutect2, varscan2
- CTNNA3 | c.2496C>T p.I832= | Silent (SNP) | VAF 130/475 reads (27%) | called by muse, mutect2, varscan2
- CXorf66 | c.672A>G p.E224= | Silent (SNP) | VAF 99/484 reads (20%) | called by muse, mutect2, varscan2
- CYP2C19 | c.195C>T p.F65= | Silent (SNP) | VAF 93/336 reads (28%) | called by muse, mutect2, varscan2
- CYP2C19 | c.678C>T p.F226= | Silent (SNP) | VAF 61/228 reads (27%) | catalogued as rs1316237390, COSV64906794; called by muse, mutect2, varscan2
- CYP2E1 | c.870C>T p.T290= | Silent (SNP) | VAF 111/754 reads (15%) | catalogued as rs149170969; called by muse, mutect2, varscan2
- DDR1 | c.1887C>T p.V629= (on ENST00000324771; = p.V592= on NM_001954.4) | Silent (SNP) | VAF 61/378 reads (16%) | catalogued as rs376611147; called by muse, mutect2, varscan2
- DISP3 | c.3768C>T p.V1256= | Silent (SNP) | VAF 130/385 reads (34%) | catalogued as rs772794796; called by muse, mutect2, varscan2
- DNAH17 | c.9159G>A p.Q3053= | Silent (SNP) | VAF 67/294 reads (23%) | called by muse, mutect2, varscan2
- DNAH17 | c.8817G>A p.R2939= | Silent (SNP) | VAF 84/360 reads (23%) | catalogued as COSV67760561; called by muse, mutect2, varscan2
- DNAJB4 | c.306C>T p.F102= | Silent (SNP) | VAF 75/344 reads (22%) | catalogued as rs745865013, COSV66131356; called by muse, mutect2, varscan2
- DPYS | c.1284C>T p.F428= | Silent (SNP) | VAF 87/458 reads (19%) | catalogued as rs769020409, COSV60907786; called by muse, mutect2, varscan2
- DRGX | c.783G>A p.K261= | Silent (SNP) | VAF 41/299 reads (14%) | called by muse, mutect2, varscan2
- DSP | c.8523C>T p.S2841= | Silent (SNP) | VAF 87/415 reads (21%) | called by muse, mutect2, varscan2
- ECM2 | c.91A>C p.R31= | Silent (SNP) | VAF 79/361 reads (22%) | called by muse, mutect2, varscan2
- EPHA10 | c.2607G>A p.R869= | Silent (SNP) | VAF 16/534 reads (3%) | catalogued as COSV57624647; called by muse, mutect2
- EPN1 | c.294G>A p.E98= | Silent (SNP) | VAF 16/503 reads (3%) | called by muse, mutect2
- EPS8L3 | c.1230C>T p.S410= | Silent (SNP) | VAF 169/358 reads (47%) | called by muse, mutect2, varscan2
- EXOC3L2 | c.297G>A p.R99= | Silent (SNP) | VAF 233/590 reads (39%) | called by muse, mutect2
- FADS6 | c.495G>A p.G165= | Silent (SNP) | VAF 102/577 reads (18%) | catalogued as rs963069234, COSV59601235; called by muse, mutect2, varscan2
- FAT2 | c.1977G>A p.V659= | Silent (SNP) | VAF 108/471 reads (23%) | called by muse, mutect2, varscan2
- FCRL1 | c.882C>T p.F294= | Silent (SNP) | VAF 91/205 reads (44%) | catalogued as COSV63827045; called by muse, mutect2, varscan2
- FFAR1 | c.399C>T p.L133= | Silent (SNP) | VAF 81/744 reads (11%) | catalogued as rs773653229, COSV99323827; called by muse, mutect2, varscan2
- G6PC | c.1023C>T p.I341= | Silent (SNP) | VAF 84/478 reads (18%) | catalogued as COSV53831033; called by muse, mutect2
- GANC | c.2106C>T p.F702= | Silent (SNP) | VAF 30/355 reads (8%) | catalogued as COSV100530998; called by muse, mutect2
- GIMAP5 | c.610C>T p.L204= | Silent (SNP) | VAF 97/577 reads (17%) | called by muse, mutect2, varscan2
- GOLGA8S | c.936G>A p.R312= | Silent (SNP) | VAF 107/653 reads (16%) | catalogued as rs1482859298; called by muse, mutect2, varscan2
- GPRC5C | c.184C>T p.L62= (on ENST00000652232; = p.L17= on NM_018653.4) | Silent (SNP) | VAF 146/515 reads (28%) | called by muse, mutect2, varscan2
- GRID2IP | c.1521C>T p.L507= | Silent (SNP) | VAF 89/492 reads (18%) | called by muse, mutect2, varscan2
- GRIP2 | c.426G>A p.G142= (on ENST00000619221; = p.G45= on NM_001080423.4) | Silent (SNP) | VAF 49/254 reads (19%) | called by muse, mutect2, varscan2
- HS3ST3A1 | c.729G>A p.R243= | Silent (SNP) | VAF 119/552 reads (22%) | called by muse, mutect2, varscan2
- HSD3B1 | c.357C>T p.V119= | Silent (SNP) | VAF 71/687 reads (10%) | called by muse, mutect2, varscan2
- IFNA13 | c.309G>A p.E103= | Silent (SNP) | VAF 16/125 reads (13%) | called by muse, mutect2, varscan2
- IGF2 | c.603G>A p.E201= (on ENST00000434045 / NM_001127598.3; = p.E145= on NM_000612.6) | Silent (SNP) | VAF 22/790 reads (3%) | called by muse, mutect2
- IGHV3-53 | c.183G>A p.G61= | Silent (SNP) | VAF 59/196 reads (30%) | called by muse, mutect2, varscan2
- IGHV3-66 | c.183G>A p.G61= | Silent (SNP) | VAF 36/380 reads (9%) | called by muse, mutect2
- IGKV3D-11 | c.27C>T p.F9= | Silent (SNP) | VAF 46/324 reads (14%) | called by muse, mutect2, varscan2
- IGSF10 | c.1695G>A p.R565= | Silent (SNP) | VAF 112/451 reads (25%) | catalogued as rs758154653, COSV56782287; called by muse, mutect2, varscan2
- IL1R2 | c.396C>T p.F132= | Silent (SNP) | VAF 64/334 reads (19%) | catalogued as rs1260972600; called by muse, mutect2, varscan2
- INSR | c.3621C>T p.S1207= | Silent (SNP) | VAF 82/341 reads (24%) | catalogued as rs778681780; called by muse, mutect2, varscan2
- IRX2 | c.1227G>A p.R409= | Silent (SNP) | VAF 128/586 reads (22%) | catalogued as rs750972100; called by muse, mutect2, varscan2
- IRX3 | c.750G>A p.E250= | Silent (SNP) | VAF 98/559 reads (18%) | called by muse, mutect2, varscan2
- KCNH7 | c.1755C>T p.I585= | Silent (SNP) | VAF 18/588 reads (3%) | catalogued as COSV59784387; called by muse, mutect2
- KCNQ2 | c.1830G>A p.E610= (on ENST00000359125 / NM_172107.4; = p.E582= on NM_004518.6) | Silent (SNP) | VAF 109/451 reads (24%) | called by muse, mutect2, varscan2
- KDM3A | c.2928G>A p.V976= | Silent (SNP) | VAF 20/250 reads (8%) | called by muse, mutect2
- KIF16B | c.3576C>T p.V1192= | Silent (SNP) | VAF 80/313 reads (26%) | catalogued as rs1320672188; called by muse, mutect2, varscan2
- KLHL15 | c.1290C>T p.I430= | Silent (SNP) | VAF 52/629 reads (8%) | called by muse, mutect2
- KLHL29 | c.18C>T p.S6= | Silent (SNP) | VAF 77/309 reads (25%) | called by muse, mutect2, varscan2
- KLHL34 | c.492G>A p.R164= | Silent (SNP) | VAF 18/642 reads (3%) | called by muse, mutect2
- KLRG1 | c.24C>T p.S8= | Silent (SNP) | VAF 88/337 reads (26%) | called by muse, mutect2, varscan2
- KRT6B | c.1608G>A p.G536= | Silent (SNP) | VAF 51/479 reads (11%) | catalogued as rs781682935; called by muse, mutect2, varscan2
- LBP | c.625C>T p.L209= | Silent (SNP) | VAF 87/346 reads (25%) | called by muse, mutect2, varscan2
- LPO | c.1371C>T p.S457= | Silent (SNP) | VAF 68/576 reads (12%) | catalogued as rs1257408731; called by muse, mutect2, varscan2
- LRRC53 | c.1341G>A p.R447= | Silent (SNP) | VAF 13/398 reads (3%) | catalogued as COSV53952486; called by muse, mutect2
- LUZP1 | c.1878G>A p.G626= | Silent (SNP) | VAF 107/253 reads (42%) | called by muse, mutect2, varscan2
- MAMLD1 | c.1563C>T p.I521= | Silent (SNP) | VAF 155/705 reads (22%) | called by muse, mutect2, varscan2
- MAP3K10 | c.2361C>T p.P787= | Silent (SNP) | VAF 222/525 reads (42%) | catalogued as rs1317174116; called by muse, mutect2, varscan2
- MAP3K5 | c.3463T>C p.L1155= | Silent (SNP) | VAF 88/363 reads (24%) | called by muse, mutect2, varscan2
- MARF1 | c.4311C>T p.L1437= | Silent (SNP) | VAF 123/523 reads (24%) | catalogued as COSV60026995; called by muse, mutect2, varscan2
- MICU1 | c.633C>T p.F211= (on ENST00000361114 / NM_001195518.2; = p.F217= on NM_006077.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 68/256 reads (27%) | called by muse, mutect2, varscan2
- MPST | c.366C>T p.H122= (on ENST00000341116 / NM_001369904.2; = p.H142= on NM_021126.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 78/1265 reads (6%) | catalogued as rs1289439794; called by muse, mutect2
- MUC12 | c.13860C>T p.F4620= (on ENST00000379442; = p.F4477= on NM_001164462.1) | Silent (SNP) | VAF 42/218 reads (19%) | catalogued as rs1158858605, COSV65211330; called by mutect2, varscan2
- MUC16 | c.38994C>T p.S12998= | Silent (SNP) | VAF 56/356 reads (16%) | called by muse, mutect2, varscan2
- MUC16 | c.38274C>T p.S12758= | Silent (SNP) | VAF 25/188 reads (13%) | catalogued as rs568692665, COSV101198965; called by muse, mutect2, varscan2
- MUC16 | c.23985T>A p.S7995= | Silent (SNP) | VAF 153/529 reads (29%) | called by muse, mutect2, varscan2
- MUC16 | c.20172C>T p.S6724= | Silent (SNP) | VAF 78/436 reads (18%) | catalogued as rs753912954; called by muse, mutect2, varscan2
- NAALADL1 | c.1542A>C p.A514= | Silent (SNP) | VAF 117/418 reads (28%) | called by muse, mutect2, varscan2
- NAIP | c.330G>A p.T110= | Silent (SNP) | VAF 164/661 reads (25%) | catalogued as rs770279208, COSV52000636, COSV52001864; called by muse, mutect2, varscan2
- NLGN4X | c.1032C>T p.I344= | Silent (SNP) | VAF 23/812 reads (3%) | catalogued as rs1216086207, COSV52012402, COSV52041335; called by muse, mutect2
- NOP14 | c.570A>G p.K190= | Silent (SNP) | VAF 349/673 reads (52%) | catalogued as rs1006083591; called by muse, mutect2, varscan2
- NPHS1 | c.807G>A p.G269= | Silent (SNP) | VAF 59/492 reads (12%) | called by muse, mutect2, varscan2
- NTF3 | c.99C>T p.S33= | Silent (SNP) | VAF 91/424 reads (21%) | catalogued as rs774180898; called by muse, mutect2, varscan2
- NWD1 | c.3492G>A p.L1164= | Silent (SNP) | VAF 107/447 reads (24%) | catalogued as COSV100341896; called by muse, mutect2, varscan2
- OGDH | c.309C>T p.S103= | Silent (SNP) | VAF 242/710 reads (34%) | catalogued as COSV56046257; called by muse, mutect2, varscan2
- OGDHL | c.2727G>A p.E909= | Silent (SNP) | VAF 77/300 reads (26%) | called by muse, mutect2, varscan2
- OR10AC1 | c.243C>T p.S81= | Silent (SNP) | VAF 251/509 reads (49%) | called by muse, mutect2, varscan2
- OR13C8 | c.606G>A p.S202= | Silent (SNP) | VAF 152/425 reads (36%) | catalogued as rs146773946; called by muse, mutect2, varscan2
- OR13J1 | c.879G>A p.R293= | Silent (SNP) | VAF 141/386 reads (37%) | catalogued as rs1012526917, COSV65069760; called by muse, mutect2, varscan2
- OR2K2 | c.768C>T p.I256= (on ENST00000374428; = p.I227= on NM_205859.2) | Silent (SNP) | VAF 88/468 reads (19%) | catalogued as rs923046534, COSV100235110; called by muse, mutect2, varscan2
- OR4C15 | c.1029G>A p.R343= (on ENST00000314644; = p.R289= on NM_001001920.2) | Silent (SNP) | VAF 95/331 reads (29%) | catalogued as rs1376535868, COSV58952769, COSV99042563; called by muse, mutect2, varscan2
- OR5AK2 | c.663C>T p.I221= | Silent (SNP) | VAF 100/499 reads (20%) | catalogued as rs1433966355, COSV58804143; called by muse, mutect2, varscan2
- OR5D3P | c.780C>T p.F260= | Silent (SNP) | VAF 94/369 reads (25%) | called by muse, varscan2
- PAAF1 | c.429C>T p.F143= | Silent (SNP) | VAF 129/508 reads (25%) | called by muse, mutect2, varscan2
- PCDHB5 | c.1611C>T p.S537= | Silent (SNP) | VAF 162/796 reads (20%) | catalogued as COSV99169249; called by muse, mutect2, varscan2
- PER2 | c.2757C>T p.N919= | Silent (SNP) | VAF 84/558 reads (15%) | catalogued as rs1343801469; called by muse, mutect2, varscan2
- PHYHIP | c.696C>T p.Y232= | Silent (SNP) | VAF 103/482 reads (21%) | called by muse, mutect2, varscan2
- PITPNM3 | c.1719C>T p.L573= | Silent (SNP) | VAF 18/453 reads (4%) | called by muse, mutect2
- PLB1 | c.24C>T p.F8= | Silent (SNP) | VAF 66/335 reads (20%) | catalogued as rs1366886943, COSV59822884; called by muse, mutect2, varscan2
- PLEKHG4B | c.762G>A p.L254= (on ENST00000283426; = p.L610= on NM_052909.5) | Silent (SNP) | VAF 40/393 reads (10%) | called by muse, mutect2, varscan2
- PLEKHG6 | c.2259G>A p.G753= | Silent (SNP) | VAF 123/651 reads (19%) | called by muse, mutect2, varscan2
- POU2F3 | c.672C>T p.F224= | Silent (SNP) | VAF 30/310 reads (10%) | catalogued as rs767041235; called by muse, mutect2
- PRKCG | c.282G>A p.T94= | Silent (SNP) | VAF 89/428 reads (21%) | catalogued as rs759030444, COSV54728188; called by muse, mutect2, varscan2
- PTPDC1 | c.1987T>C p.L663= (on ENST00000375360 / NM_177995.3; = p.L715= on NM_152422.4) | Silent (SNP) | VAF 98/428 reads (23%) | catalogued as rs753925904; called by muse, mutect2, varscan2
- PTPN4 | c.1860C>T p.F620= | Silent (SNP) | VAF 14/344 reads (4%) | called by muse, mutect2
- RADIL | c.1756C>T p.L586= | Silent (SNP) | VAF 84/558 reads (15%) | called by muse, mutect2, varscan2
- RADIL | c.1755C>T p.L585= | Silent (SNP) | VAF 76/520 reads (15%) | called by muse, varscan2
- RANBP2 | c.4041G>A p.Q1347= | Silent (SNP) | VAF 48/474 reads (10%) | catalogued as COSV99313777; called by muse, mutect2
- RBMXL2 | c.684C>T p.P228= | Silent (SNP) | VAF 118/522 reads (23%) | called by muse, mutect2, varscan2
- RBP3 | c.2889C>T p.T963= | Silent (SNP) | VAF 166/510 reads (33%) | called by muse, mutect2, varscan2
- RELN | c.2547G>A p.Q849= | Silent (SNP) | VAF 131/345 reads (38%) | catalogued as rs762338735; called by muse, mutect2, varscan2
- RING1 | c.765C>T p.P255= | Silent (SNP) | VAF 117/542 reads (22%) | catalogued as rs1217356179; called by muse, mutect2, varscan2
- RPS28 | c.51C>G p.V17= | Silent (SNP) | VAF 122/465 reads (26%) | called by muse, mutect2, varscan2
- RTL1 | c.3942A>G p.A1314= | Silent (SNP) | VAF 110/334 reads (33%) | called by muse, mutect2, varscan2
- RTP5 | c.1245C>T p.S415= | Silent (SNP) | VAF 139/612 reads (23%) | called by muse, mutect2, varscan2
- SCML4 | c.54C>T p.S18= | Silent (SNP) | VAF 111/447 reads (25%) | called by muse, mutect2, varscan2
- SCN10A | c.171G>A p.L57= | Silent (SNP) | VAF 113/515 reads (22%) | called by muse, varscan2
- SELP | c.2040A>G p.G680= | Silent (SNP) | VAF 170/368 reads (46%) | called by muse, mutect2, varscan2
- SEMA3G | c.303G>A p.Q101= | Silent (SNP) | VAF 109/487 reads (22%) | catalogued as rs769099931; called by muse, mutect2, varscan2
- SFTPD | c.615G>A p.G205= | Silent (SNP) | VAF 132/489 reads (27%) | called by muse, mutect2, varscan2
- SH3D21 | c.1524G>A p.S508= (on ENST00000453908 / NM_001162530.2; = p.S397= on NM_024676.5) | Silent (SNP) | VAF 126/567 reads (22%) | catalogued as rs373656908; called by muse, mutect2, varscan2
- SHISA8 | c.487C>T p.*163= (on ENST00000457093; = p.L196= on NM_001207020.2 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 94/1184 reads (8%) | called by muse, mutect2
- SIGLEC11 | c.231G>A p.R77= | Silent (SNP) | VAF 58/596 reads (10%) | catalogued as COSV70221937; called by muse, mutect2
- SIRT2 | c.717C>T p.L239= | Silent (SNP) | VAF 43/403 reads (11%) | called by muse, mutect2, varscan2
- SLC17A2 | c.381G>A p.L127= | Silent (SNP) | VAF 133/450 reads (30%) | catalogued as COSV55352929, COSV55354442; called by muse, mutect2, varscan2
- SLC22A24 | c.96C>T p.F32= | Silent (SNP) | VAF 109/456 reads (24%) | catalogued as COSV100400123; called by muse, mutect2, varscan2
- SLC30A4 | c.726T>C p.R242= | Silent (SNP) | VAF 59/363 reads (16%) | called by muse, mutect2, varscan2
- SLC30A8 | c.174G>A p.K58= | Silent (SNP) | VAF 107/510 reads (21%) | catalogued as COSV69969283; called by muse, mutect2, varscan2
- SLCO1B3 | c.1605C>T p.F535= | Silent (SNP) | VAF 96/394 reads (24%) | catalogued as COSV53932033; called by muse, mutect2, varscan2
- ST8SIA5 | c.1098C>T p.L366= | Silent (SNP) | VAF 76/273 reads (28%) | called by muse, mutect2, varscan2
- TAC1 | c.120C>T p.I40= | Silent (SNP) | VAF 53/310 reads (17%) | catalogued as COSV100071252; called by muse, mutect2, varscan2
- TACC2 | c.7200C>T p.I2400= (on ENST00000334433; = p.I478= on NM_006997.4) | Silent (SNP) | VAF 109/453 reads (24%) | catalogued as COSV53281653; called by muse, mutect2, varscan2
- TCEAL6 | c.462G>A p.R154= | Silent (SNP) | VAF 138/556 reads (25%) | called by muse, mutect2, varscan2
- TEX2 | c.486C>T p.S162= | Silent (SNP) | VAF 76/511 reads (15%) | called by muse, mutect2, varscan2
- THAP6 | c.480C>T p.G160= | Silent (SNP) | VAF 110/342 reads (32%) | catalogued as rs767607083, COSV61162406; called by muse, mutect2, varscan2
- THBS2 | c.591C>A p.A197= | Silent (SNP) | VAF 53/268 reads (20%) | called by muse, varscan2
- TLR8 | c.1977C>T p.F659= (on ENST00000218032 / NM_138636.5; = p.F677= on NM_016610.4) | Silent (SNP) | VAF 87/362 reads (24%) | catalogued as rs766184252, COSV54318577; called by muse, mutect2, varscan2
- TMC5 | c.1413C>T p.I471= (on ENST00000396229 / NM_001105248.1; = p.I225= on NM_024780.5) | Silent (SNP) | VAF 63/413 reads (15%) | catalogued as rs1405838984; called by muse, mutect2, varscan2
- TMEM255A | c.27G>A p.R9= | Silent (SNP) | VAF 95/410 reads (23%) | catalogued as COSV59029958; called by muse, mutect2, varscan2
- TNC | c.2433G>A p.V811= | Silent (SNP) | VAF 75/376 reads (20%) | catalogued as rs1375352740; called by muse, mutect2, varscan2
- TNNC1 | c.30G>A p.E10= | Silent (SNP) | VAF 90/351 reads (26%) | called by muse, mutect2, varscan2
- TPM4 | c.66G>A p.A22= | Silent (SNP) | VAF 97/372 reads (26%) | catalogued as COSV100783735; called by muse, mutect2, varscan2
- TRIB1 | c.225T>C p.A75= | Silent (SNP) | VAF 135/562 reads (24%) | called by muse, mutect2, varscan2
- TRIM75P | c.609C>T p.S203= | Silent (SNP) | VAF 70/250 reads (28%) | called by muse, mutect2, varscan2
- TRPC4 | c.1101C>T p.I367= | Silent (SNP) | VAF 140/500 reads (28%) | catalogued as COSV58993189; called by muse, mutect2, varscan2
- TSPAN13 | c.288T>C p.C96= | Silent (SNP) | VAF 131/383 reads (34%) | called by muse, mutect2, varscan2
- TSSK1B | c.42G>A p.L14= | Silent (SNP) | VAF 77/370 reads (21%) | catalogued as rs775538333; called by muse, mutect2, varscan2
- TTN | c.3549C>T p.S1183= (on ENST00000591111; = p.S1137= on NM_003319.4) | Silent (SNP) | VAF 64/299 reads (21%) | catalogued as rs764819788, COSV60345883; called by muse, mutect2, varscan2
- VWA7 | c.906G>A p.R302= | Silent (SNP) | VAF 136/574 reads (24%) | catalogued as rs779590124; called by muse, mutect2, varscan2
- WDR33 | c.2190C>T p.G730= | Silent (SNP) | VAF 85/425 reads (20%) | catalogued as rs528369566; called by muse, mutect2, varscan2
- ZAN | c.2202C>T p.S734= | Silent (SNP) | VAF 179/524 reads (34%) | catalogued as COSV61810236; called by muse, mutect2, varscan2
- ZFHX2 | c.948G>A p.A316= | Silent (SNP) | VAF 107/417 reads (26%) | catalogued as rs777886928; called by muse, mutect2, varscan2
- ZFHX4 | c.4302C>T p.F1434= | Silent (SNP) | VAF 106/530 reads (20%) | catalogued as COSV50491183; called by muse, mutect2, varscan2
- ZNF722P | c.54C>T p.F18= | Silent (SNP) | VAF 82/308 reads (27%) | called by muse, mutect2, varscan2
- ZRANB3 | c.2679G>A p.K893= | Silent (SNP) | VAF 71/443 reads (16%) | called by muse, mutect2, varscan2
- ZSCAN18 | c.144C>T p.S48= | Silent (SNP) | VAF 210/550 reads (38%) | catalogued as rs868515616; called by muse, mutect2, varscan2
- ADRA1A | c.884-8618C>T | Intron (SNP) | VAF 71/253 reads (28%) | called by muse, mutect2, varscan2
- ARHGAP45 | chr19:1066121 C>T | 5'Flank (SNP) | VAF 66/464 reads (14%) | catalogued as rs762679893; called by muse, mutect2, varscan2
- ARHGAP45 | chr19:1066122 C>T | 5'Flank (SNP) | VAF 65/461 reads (14%) | called by muse, mutect2, varscan2
- C1RL | chr12:7093861 G>A | 3'Flank (SNP) | VAF 68/394 reads (17%) | called by muse, mutect2, varscan2
- CD300LG | c.379+31G>A | Intron (SNP) | VAF 119/513 reads (23%) | called by muse, mutect2, varscan2
- GABRG2 | chr5:162067634 G>A | 5'Flank (SNP) | VAF 103/474 reads (22%) | called by muse, mutect2, varscan2
- GCNT1 | c.*1160A>G | 3'UTR (SNP) | VAF 127/423 reads (30%) | catalogued as rs764430791; called by muse, mutect2, varscan2
- H2BP2 | n.1061+558C>T | Intron (SNP) | VAF 34/350 reads (10%) | called by muse, mutect2, varscan2
- IGFN1 | c.1241+1648G>A | Intron (SNP) | VAF 114/464 reads (25%) | called by muse, mutect2, varscan2
- IGSF22 | c.2096-1265G>A | Intron (SNP) | VAF 64/298 reads (21%) | called by muse, mutect2, varscan2
- ISCA2 | c.-1G>A | 5'UTR (SNP) | VAF 110/330 reads (33%) | catalogued as rs1482088986; called by muse, mutect2, varscan2
- KCNQ1 | c.1393+25021G>A | Intron (SNP) | VAF 59/306 reads (19%) | catalogued as rs1345355830; called by muse, mutect2, varscan2
- KCNQ1 | c.1393+31150G>A | Intron (SNP) | VAF 73/352 reads (21%) | called by muse, mutect2, varscan2
- KCNQ1 | c.1394-7792G>A | Intron (SNP) | VAF 67/401 reads (17%) | called by muse, mutect2, varscan2
- KCNQ1 | c.1514+9997G>A | Intron (SNP) | VAF 12/360 reads (3%) | called by muse, mutect2
- KCNQ1 | c.1514+16676G>A | Intron (SNP) | VAF 59/271 reads (22%) | called by muse, mutect2, varscan2
- NEDD4L | c.297+3817C>T | Intron (SNP) | VAF 26/514 reads (5%) | called by muse, mutect2
- OBSCN | c.6754+208C>T | Intron (SNP) | VAF 88/357 reads (25%) | catalogued as rs372936044; ClinVar: likely benign; called by muse, mutect2, varscan2
- PDE9A | c.219-1530C>T | Intron (SNP) | VAF 91/297 reads (31%) | called by muse, mutect2, varscan2
- PLPPR3 | c.657+30G>A | Intron (SNP) | VAF 125/559 reads (22%) | called by muse, mutect2, varscan2
- PNO1 | chr2:68157808 C>T | 5'Flank (SNP) | VAF 56/299 reads (19%) | called by muse, mutect2, varscan2
- PROZ | c.70+528G>A | Intron (SNP) | VAF 82/454 reads (18%) | called by muse, mutect2, varscan2
- SEC16A | c.6313-121C>T | Intron (SNP) | VAF 114/510 reads (22%) | catalogued as COSV51529828; called by muse, varscan2
- SYT7 | c.215+8863G>A | Intron (SNP) | VAF 114/403 reads (28%) | called by muse, mutect2, varscan2
- TTN | c.10361-3738G>A | Intron (SNP) | VAF 54/346 reads (16%) | catalogued as COSV100636135; called by muse, mutect2, varscan2
- TTN | c.10360+1999A>C | Intron (SNP) | VAF 53/276 reads (19%) | catalogued as COSV59864318; called by muse, mutect2, varscan2
